HCMI case HCM-WCMC-0790-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7d2af728-4620-4ed4-946c-70956f6e6f57

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive.

Diagnoses (1)
1. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.2; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Lateral wall of bladder; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,784 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 94 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Doxorubicin + Methotrexate + Vinblastine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: MVAC-Growth Factor Regimen; Days to treatment start: 167 days; Days to treatment end: 211 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,589 days (4.4 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 910.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93.4 kg; Height: 180.3 cm; BMI: 29.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 1; Alcohol days per week: 6.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-WCMC-0790-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0790-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
